Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A5TR, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A5TR-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: Location: Received:
Gender: M Accnt Reported:
Physician(s):
Phy Location:

Clinical History

Brain tumor

Operative Diagnoses

Operation / Specimen

A: Brain, first priority, biopsy

B: Brain, remainder, biopsy

C: Brain, posterior rim, biopsy

D: Brain, temporal tumor, biopsy

Pathologic Diagnosis

A. - D. Brain, tumor, biopsies and excision: Oligoastrocytoma, WHO Grade II (see comment).

Comment

Permanent sections confirm the frozen section diagnosis. Sections of A. and B. show a mostly astrocytic appearing

glial neoplasm. C. and D. are larger specimens and display mostly oligodendroglial features with mostly round nuclear

morphology, ropy myelin, delicate vessels and microcyst formation. Rare mitotic figures are noted in specimen D.

Microvascular proliferation and/or necrosis is not identified. The Ki-67 labeling index is up to approximately 5%. The

IDH1 R132H mutation antibody is negative. Controls show appropriate immunoreactivity.

The very focal mitotic activity seen in specimen D. may reflect that the lesion could be in transition to a higher grade.

Clinical correlation is recommended.

Electronically Signed Out

Senior Staff Pathologist

Procedures/Addenda

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Surgical Pathology

Page 2 of 4

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification

of methylated and unmethylated DNA

sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into

ICD-0-3
Oligoastrocytoma
Grade II 9382/3

Date Supratentorial NOS
C71.0
Brain, temporal lobe
C71.2
JW 4/18/13

[page 2 of 3]
unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered:

Date Reported:

Interpretation

Findings suggestive of partial deletion of chromosome arm 19q on locus D19S606 (D19S412, D19S1182 - no evidence of loss of heterozygosity).

NEGATIVE: Allelic loss on chromosome arm 1p is NOT detected.

Informative loci are: D1S548, D1S592, D1S552, D1S1612, D19S412, D19S606, and D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

DNA extracted from a

corresponding blood specimen was used as a normal reference control.

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

Surgical Pathology

Page 3 of 4

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

[page 3 of 3]
TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain, first priority, biopsy: Apical glial proliferation suspicious for astrocytoma. Frozen section and smears performed at _____ and results reported to the Physician of Record.

Senior Staff Pathologist

Gross Description

A. Brain, first priority, biopsy: received fresh and labeled "Pathology for priority - f.s." is a 0.8 cm aggregate of tan-grey soft tissue, of which a portion is submitted for frozen section analysis.

SECTIONS:

1 frozen section remnant

2 remaining tissue.

2-NS

B. Brain, remainder, biopsy: received fresh and labeled "The rest - F.S. & perm" are multiple tan-grey soft tissue fragments, 0.9 cm in aggregate, entirely submitted for frozen section analysis.

SECTIONS:

1 frozen section remnant

C. Brain, posterior rim, biopsy: received in formalin and labeled "Posterior rim" is a 1.8 cm aggregate of soft tan-grey tissue.

2-NS

D. Brain, temporal tumor, biopsy: received in formalin and labeled "Temporal tumor" are multiple soft fragments of tan-grey brain tissue, 3.8 x 2.8 x 1.3 cm in aggregate.

5-NS

ICD-9(s): 191.9 191.9

Billing Fee Code(s):

Histo Data

Part A: Brain, first priority, biopsy

Taken: _____ Received: _____

Stain/cnt Block Ordered Comment

FS H&E x 1 1

Surgical Pathology

Page 4 of 4

Source: NCI Genomic Data Commons file 508726b1-084b-4ac8-b4aa-104b5e0f0e7c (TCGA-DU-A5TR.7BF16354-F6FD-428D-ACB3-E9F930F06C46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).